CGCI case HTMCP-01-20-00779 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/38f6a743-24b0-4b03-96cc-6bfc74def269

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 90 days; Cause of death: Infection.

Diagnoses (1)
1. Primary diffuse large B-cell lymphoma of the CNS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 51.8 years (18,925 days); Year of diagnosis: 2018; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage I; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 90 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Brain; Sites of involvement: Brain, NOS.
   Pathology details: Tumor largest dimension diameter: 3.8 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Imaging type: PET; Imaging result: Positive.
- Days to follow up: 90 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -18.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CCND1 (IHC): Negative.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD30 (IHC): Positive.
- CD5 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC (Cytogenetics, NOS): Normal.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Test (IHC): Positive; Specialized molecular test: EBER.
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 2596 [Blood test normal range upper: 610].

Other clinical attributes
- Day -18: Comorbidities: HIV/AIDS.
- Day -18: Risk factors: HIV/AIDS.
- Day 0: Comorbidities: Cytomegalovirus (CMV).
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Risk factors: Cytomegalovirus (CMV).
- Day 0: Weight: 145 kg; Height: 175 cm; BMI: 47.3; CD4 count: 10; Haart treatment indicator: No; HIV viral load: 497993.
- Day 90: Nadir CD4 count: 10.

Exposures
- Tobacco smoking status: Current Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-20-00779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-20-00779-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-20-00779-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Primary DLBCL of the CNS; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Cause of death other: sepsis, febrile neutropenia, Acute hypoxic resp. failure; Tumor status: With tumor; Tobacco smoking history indicator: 2; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: CMV.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Primary pathology: Extranodal site involvement: 1; Method initial path diagnosis: Biopsy (all types); Days from index date to tumor sample procurement: -5; Lymph nodes examined: No.
- Tests performed: LDH level: 2596; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: Cyclin D1; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc; Genetic abnormality method other: Cytogenetics.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-20-00779-01A-01E-13575:
- % tumour top: 50
- % tumour bottom: 50

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-20-00779-01A-01S-13575:
- % tumour top: 50
- % tumour bottom: 50
